Somatic mutation profile of tumor specimen MMRF_1700_1_BM_CD138pos (aliquot MMRF_1700_1_BM_CD138pos_T1_KBS5U_L05380) from MMRF case MMRF_1700, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.8 years (27,692 days).
Specimen MMRF_1700_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37175c3d-a6e5-4a2a-a926-d78c4982c705.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1700_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1700_1_PB_Whole_C3_KBS5U_L05393; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b506b1b-7e81-4836-88b0-064e83d24976

The open-access MAF lists 119 somatic variants for this specimen: 42 protein-altering or splice-affecting, 21 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 34, Silent 21, Intron 10, Nonsense Mutation 4, RNA 4, 5'UTR 3, 3'Flank 3, Frame Shift Del 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 29/41 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.369G>T p.W123C | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs202137941; called by muse, mutect2, varscan2
- CDCA7L | c.230C>A p.T77N | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as rs776912112; called by muse, mutect2, varscan2
- CDK11A | c.1889C>A p.S630* (on ENST00000378633 / NM_001313896.2; = p.S627* on NM_024011.4) | Nonsense Mutation (SNP) | VAF 90/184 reads (49%) | catalogued as rs757293035, COSV52307726, COSV99319203; called by muse, mutect2, varscan2
- CDS1 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs775262819; called by muse, mutect2, varscan2
- CEP290 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV58354584; called by muse, mutect2, varscan2
- ERBB4 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53508555; called by muse, mutect2, varscan2
- GANC | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 20/231 reads (9%) | PolyPhen probably damaging (0.993); catalogued as rs753728748, COSV58808181; called by muse, mutect2
- HOXD11 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs1395005679; called by muse, mutect2, varscan2
- IGHV2-70 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs777686921; called by muse, varscan2
- IGHV2-70 | c.225T>G p.D75E | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs373801344; called by muse, varscan2
- IGKJ4 | c.23A>T p.K8M | Missense Mutation (SNP) | VAF 28/49 reads (57%) | PolyPhen benign (0.27); catalogued as rs147540982; called by muse, varscan2
- IP6K3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs537814047; called by muse, varscan2
- KCNMA1 | c.3149C>T p.T1050M (on ENST00000286628 / NM_001161352.2; = p.T992M on NM_002247.4) | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs915080941; called by muse, mutect2, varscan2
- KLF2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1404814458, COSV50179850; called by muse, mutect2
- MED15 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.12); catalogued as rs774118258; called by muse, mutect2, varscan2
- NRXN2 | c.3175C>T p.R1059W | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200881363, COSV55454740; called by muse, mutect2, varscan2
- PPP1R1C | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 37/82 reads (45%) | catalogued as rs1489694914; called by muse, mutect2, varscan2
- SORCS2 | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs372065575; called by muse, mutect2, varscan2
- WDR6 | c.386T>C p.I129T | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs774083749; called by muse, mutect2, varscan2
- AL645922.1 | c.1607A>G p.Q536R | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- CARMIL2 | c.3565G>A p.G1189S | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC141 | c.3986A>G p.E1329G | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CCDC168 | c.13838C>A p.T4613K | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- CNTN5 | c.589T>G p.F197V | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FAM120AOS | c.412T>C p.F138L | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- FIG4 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FLOT1 | c.831G>C p.K277N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- IGHV2-70D | c.8T>A p.I3K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, varscan2
- IWS1 | c.988_995del p.D330Qfs*6 | Frame Shift Del (DEL) | VAF 85/106 reads (80%) | called by mutect2, pindel, varscan2
- KIAA1958 | c.2101T>C p.S701P | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- KIT | c.1412A>T p.K471M | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MAGEL2 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- MAT2B | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- MPDZ | c.4183G>T p.A1395S | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- NID2 | c.3951C>G p.Y1317* | Nonsense Mutation (SNP) | VAF 60/133 reads (45%) | called by muse, mutect2, varscan2
- NOBOX | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- PGGHG | c.205_206delinsT p.P69Lfs*8 | Frame Shift Del (DEL) | VAF 39/168 reads (23%) | called by pindel, varscan2*
- SAMHD1 | c.1424C>A p.S475Y | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SGCG | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.089); called by muse, mutect2
- ZNF648 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF804A | c.2949G>C p.K983N | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ASTE1 | c.963G>A p.L321= | Silent (SNP) | VAF 67/216 reads (31%) | called by muse, mutect2, varscan2
- BAIAP2L2 | c.1236C>T p.N412= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV57635065; called by mutect2, varscan2
- BHLHE41 | c.1126C>T p.L376= | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, varscan2
- FBXW12 | c.1338T>C p.L446= | Silent (SNP) | VAF 39/131 reads (30%) | called by muse, mutect2, varscan2
- FILIP1 | c.228C>A p.S76= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV52732404; called by muse, mutect2, varscan2
- FLG2 | c.4797C>T p.Y1599= | Silent (SNP) | VAF 101/209 reads (48%) | catalogued as rs747254831, COSV66167542; called by muse, mutect2, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs376111067; called by muse, varscan2
- IGHV2-70 | c.186A>T p.P62= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as rs997215308; called by muse, varscan2
- IGKJ2 | c.6C>T p.C2= | Silent (SNP) | VAF 81/90 reads (90%) | catalogued as rs375913965; called by muse, varscan2
- INSRR | c.321G>A p.T107= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as rs377729626; called by muse, mutect2, varscan2
- KHNYN | c.429C>T p.S143= | Silent (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- LRRC28 | c.277C>T p.L93= | Silent (SNP) | VAF 89/332 reads (27%) | called by muse, mutect2, varscan2
- MAP6 | c.1311G>A p.A437= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs200607557; called by muse, mutect2, varscan2
- PCDH7 | c.216C>T p.S72= | Silent (SNP) | VAF 122/243 reads (50%) | catalogued as COSV62336590; called by muse, mutect2, varscan2
- PRRT3 | c.2103G>A p.A701= | Silent (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- SIX4 | c.1119C>G p.P373= | Silent (SNP) | VAF 51/136 reads (38%) | called by muse, mutect2, varscan2
- TRPM8 | c.1980G>A p.A660= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs145636954; called by muse, mutect2, varscan2
- UBAP2 | c.546G>C p.G182= | Silent (SNP) | VAF 64/243 reads (26%) | called by muse, mutect2, varscan2
- ZBTB7A | c.1191G>A p.L397= | Silent (SNP) | VAF 65/193 reads (34%) | catalogued as rs947443348; called by muse, mutect2, varscan2
- ZNF300 | c.1665A>G p.G555= | Silent (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- ZPLD1 | c.927T>A p.L309= (on ENST00000466937 / NM_001329788.1; = p.L325= on NM_175056.2) | Silent (SNP) | VAF 76/245 reads (31%) | called by muse, mutect2, varscan2
- AFF1 | c.*2638G>A | 3'UTR (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- ANP32BP3 | n.656G>A | RNA (SNP) | VAF 75/348 reads (22%) | catalogued as rs984356872; called by muse, mutect2, varscan2
- ARHGEF10 | c.*281G>A | 3'UTR (SNP) | VAF 15/35 reads (43%) | catalogued as rs1467232149; called by muse, mutect2, varscan2
- ATP8B4 | c.2036-39A>G | Intron (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2
- BCL7A | chr12:122021407 A>T | 5'Flank (SNP) | VAF 51/63 reads (81%) | catalogued as rs566164810, COSV55850178; called by muse, mutect2, varscan2
- BGN | c.*304C>T | 3'UTR (SNP) | VAF 45/104 reads (43%) | catalogued as rs1030280353; called by muse, mutect2, varscan2
- BMP15 | chrX:50905834 G>T | 5'Flank (SNP) | VAF 17/19 reads (89%) | called by muse, mutect2, varscan2
- C4orf33 | c.-553dup | 5'UTR (INS) | VAF 31/70 reads (44%) | called by mutect2, varscan2
- CRACR2A | c.*286A>C | 3'UTR (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2
- DCLRE1B | c.*68G>A | 3'UTR (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- DES | c.*347C>T | 3'UTR (SNP) | VAF 34/76 reads (45%) | called by muse, mutect2, varscan2
- EIF4EBP1 | c.*102C>T | 3'UTR (SNP) | VAF 40/110 reads (36%) | catalogued as rs532528481; called by muse, mutect2, varscan2
- EOGT | c.*992T>C | 3'UTR (SNP) | VAF 11/14 reads (79%) | called by muse, mutect2, varscan2
- EOGT | c.*889T>C | 3'UTR (SNP) | VAF 38/38 reads (100%) | called by muse, mutect2, varscan2
- EOGT | c.*770T>C | 3'UTR (SNP) | VAF 31/33 reads (94%) | called by muse, mutect2, varscan2
- FBLN2 | c.*23G>A | 3'UTR (SNP) | VAF 39/79 reads (49%) | catalogued as rs556247082, COSV99851556; called by muse, mutect2, varscan2
- FTHL17 | c.-4C>T | 5'UTR (SNP) | VAF 57/62 reads (92%) | catalogued as rs1315767751, COSV100784395, COSV63266680; called by muse, mutect2, varscan2
- GABRA5 | c.*717G>A | 3'UTR (SNP) | VAF 43/208 reads (21%) | called by muse, mutect2, varscan2
- GALNT13 | c.1531-3682G>A | Intron (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2, varscan2
- GAS7 | c.886-21G>A | Intron (SNP) | VAF 52/95 reads (55%) | called by muse, mutect2, varscan2
- GZF1 | c.*1613T>G | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- H6PD | c.*3070A>C | 3'UTR (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- KIAA1549 | c.*4480G>A | 3'UTR (SNP) | VAF 66/143 reads (46%) | catalogued as rs1441816050; called by muse, mutect2, varscan2
- KLHL15 | c.*360C>G | 3'UTR (SNP) | VAF 28/37 reads (76%) | called by muse, mutect2, varscan2
- LARGE1 | c.*429T>C | 3'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- LILRB5 | c.1577-33C>A | Intron (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- LINC00602 | n.666C>A | RNA (SNP) | VAF 6/42 reads (14%) | catalogued as rs929147922; called by muse, mutect2
- LINC02693 | n.4714G>A | RNA (SNP) | VAF 26/56 reads (46%) | catalogued as rs995990409; called by muse, mutect2, varscan2
- MAP1B | c.*1679T>A | 3'UTR (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- MED28 | c.*2098C>T | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- MRPL55 | c.-58-59A>T | Intron (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2
- MYCN | c.*325T>C | 3'UTR (SNP) | VAF 22/26 reads (85%) | called by muse, mutect2, varscan2
- NKTR | c.286+775A>T | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- NRXN3 | chr14:79863991 G>C | 3'Flank (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- NTM | c.-298G>A | 5'UTR (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- PDE1C | c.1892-13417A>T | Intron (SNP) | VAF 18/34 reads (53%) | catalogued as COSV58514490; called by muse, mutect2, varscan2
- POM121B | n.1739C>T | RNA (SNP) | VAF 40/119 reads (34%) | called by muse, mutect2, varscan2
- PRKCZ | c.975-19G>A | Intron (SNP) | VAF 32/73 reads (44%) | catalogued as rs757912200; called by muse, mutect2, varscan2
- PTGS2 | c.*1459del | 3'UTR (DEL) | VAF 11/38 reads (29%) | catalogued as rs887190876; called by mutect2, varscan2
- RBM12 | chr20:35649210 T>A | 3'Flank (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- SDK2 | c.*3556G>A | 3'UTR (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- SLC30A9 | c.1662+57T>A | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- SLC44A1 | c.*1291dup | 3'UTR (INS) | VAF 9/27 reads (33%) | catalogued as rs965525535; called by mutect2, varscan2
- SLC5A3 | c.*8103G>A | 3'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- SOGA1 | c.*1245C>T | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- SPCS3 | c.*502G>C | 3'UTR (SNP) | VAF 48/98 reads (49%) | catalogued as rs908027502; called by muse, mutect2, varscan2
- TIRAP | c.646+49C>A | Intron (SNP) | VAF 53/253 reads (21%) | called by muse, mutect2, varscan2
- TRAPPC3L | c.*1673G>A | 3'UTR (SNP) | VAF 67/157 reads (43%) | called by muse, mutect2, varscan2
- UBQLN1 | c.*1500C>T | 3'UTR (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- UBR3 | c.*463_*464insC | 3'UTR (INS) | VAF 26/84 reads (31%) | called by mutect2, varscan2
- UBXN10 | c.*1995G>T | 3'UTR (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- UQCRB | c.*5058C>T | 3'UTR (SNP) | VAF 28/68 reads (41%) | catalogued as rs540795518; called by muse, mutect2, varscan2
- USP15 | chr12:62417406 T>C | 3'Flank (SNP) | VAF 16/18 reads (89%) | called by muse, mutect2, varscan2
- ZFAT | c.*162C>T | 3'UTR (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- ZFHX3 | c.*2315G>C | 3'UTR (SNP) | VAF 43/78 reads (55%) | called by muse, mutect2, varscan2
- ZNF716 | c.*864A>G | 3'UTR (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
